Somatic mutation profile of tumor specimen BA2266D (aliquot aq-BA2266D) from BEATAML1.0 case 2389, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 75.9 years (27,739 days).
Specimen BA2266D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e8a13d5-644b-4bff-afe6-14b66e4aee3e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2750D (Solid Tissue Normal), aliquot aq-BA2750D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23632567-9392-4363-b504-418feaa9aff2

The open-access MAF lists 27 somatic variants for this specimen: 20 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 4, Intron 2, Frame Shift Del 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXP1 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 8/120 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs797045586, COSV59537585; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ACP7 | c.1057C>T p.R353* | Nonsense Mutation (SNP) | VAF 14/119 reads (12%) | catalogued as rs1250019430; called by muse, mutect2
- ADAMTS16 | c.1708C>T p.R570W | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1176725522, COSV56999696; called by muse, mutect2
- DCLK2 | c.1334G>A p.R445H | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs1272086755, COSV56198689; called by muse, mutect2, varscan2
- HCRTR2 | c.307G>A p.V103M | Missense Mutation (SNP) | VAF 24/207 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201582748; called by muse, mutect2, varscan2
- NUDT10 | c.266C>G p.P89R | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs2801625; called by muse, mutect2
- PC | c.2359G>A p.A787T | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.668); catalogued as COSV99046431; called by muse, mutect2
- ADIPOR1 | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- BRD7 | c.1324G>T p.D442Y | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.458); called by muse, mutect2
- EXOC4 | c.117C>A p.D39E | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.663); called by muse, mutect2
- FAF1 | c.1585C>A p.H529N | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, varscan2
- NAP1L4 | c.743A>T p.D248V | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NDUFB4 | c.44C>A p.P15H | Missense Mutation (SNP) | VAF 13/207 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- OXTR | c.475G>T p.A159S | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.109); called by muse, mutect2
- PITPNB | c.85G>T p.A29S | Missense Mutation (SNP) | VAF 6/149 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.428); called by muse, mutect2
- PTCHD3 | c.1220G>T p.C407F | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- SERPINC1 | c.237del p.V80Sfs*34 | Frame Shift Del (DEL) | VAF 21/180 reads (12%) | called by mutect2, pindel, varscan2
- SPATA31A7 | c.2005C>T p.P669S | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.08); called by mutect2, varscan2
- TVP23A | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.81); PolyPhen benign (0.017); called by muse, mutect2
- ZZEF1 | c.1914G>T p.R638S | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.123); called by muse, mutect2
- KCNS3 | c.702C>T p.T234= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as rs758622857; called by muse, mutect2, varscan2
- MAGEC2 | c.348C>A p.S116= | Silent (SNP) | VAF 19/104 reads (18%) | called by muse, mutect2, varscan2
- PAX3 | c.1107C>T p.S369= | Silent (SNP) | VAF 38/301 reads (13%) | catalogued as rs931413137, CM162711, COSV60591826; called by muse, mutect2, varscan2
- TRIM49C | c.1074T>C p.C358= | Silent (SNP) | VAF 14/447 reads (3%) | called by muse, mutect2
- CCNH | c.314+9G>T | Intron (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- PPP5D1 | n.387G>A | RNA (SNP) | VAF 10/89 reads (11%) | called by muse, mutect2, varscan2
- TCF7 | c.1027-126C>A | Intron (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
